Gene-level copy-number profile of tumor specimen ALCH-B2NE-TTP1-A from ALCHEMIST case ALCH-B2NE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.3 years (22,007 days).
Specimen ALCH-B2NE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b72885c1-390a-4da0-a350-79b668109f17.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/e9faa231-a58b-4ce0-bcfc-8238c788623c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 19,773; copy number 2: 30,213; copy number 3: 6,931; copy number 4: 935; copy number 5: 448; copy number 6: 19; copy number 8: 74.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:70,051,651–70,104,179, 3 genes: PRDM14, RNU1-101P, H2AZP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 541 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,168,862–68,467,294, 123 genes, copy number 5–8 (broad region; genes not listed).
- chr2:69,644,425–69,942,945, 7 genes, copy number 5–6 (within-gene range 4–6): ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1.
- chr2:96,859,718–97,995,948, 43 genes, copy number 8: SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P.
- chr3:166,569,693–167,407,874, 10 genes, copy number 6 (within-gene range 3–6): LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX.
- chr8:23,458,601–23,789,487, 11 genes, copy number 5 (within-gene range 2–5): AC104561.1, AC104561.2, AC104561.4, AC104561.3, SLC25A37, RNU4-71P, SINHCAFP3, NKX3-1, NKX2-6, AC012574.1, AC012574.2.
- chr10:67,858,818–84,003,479, 347 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
